Somatic mutation profile of tumor specimen C3L-07096-01 (aliquot CPT0434230009) from CPTAC case C3L-07096, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: GX; Age at diagnosis: 49.1 years (17,943 days).
Specimen C3L-07096-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09a2fda8-1af4-4d4d-9456-c36733659072.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07096-32 (Blood Derived Normal), aliquot CPT0434380002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79d05c3b-23e7-47ce-a08c-04b6eee49d4c

The open-access MAF lists 94 somatic variants for this specimen: 62 protein-altering or splice-affecting, 27 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 27, Nonsense Mutation 3, 5'UTR 2, Intron 2, Splice Site 2, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.16412+1G>T p.X5471_splice | Splice Site (SNP) | VAF 28/404 reads (7%) | catalogued as rs794727752, CS122132, COSV56451637, COSV56483250; ClinVar: pathogenic; called by muse, mutect2
- MAP2K4 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 23/278 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62254942, COSV62259088; called by muse, mutect2
- TP53 | c.530C>G p.P177R | Missense Mutation (SNP) | VAF 36/434 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs751477326, CM102507, COSV52661381, COSV52721872, COSV52783879; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- AK9 | c.4492G>A p.D1498N | Missense Mutation (SNP) | VAF 44/245 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs994580334; called by muse, mutect2, varscan2
- APBA2 | c.1721A>T p.H574L | Missense Mutation (SNP) | VAF 53/505 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1362705807; called by muse, mutect2, varscan2
- CDH1 | c.466T>C p.W156R | Missense Mutation (SNP) | VAF 49/425 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55733295; called by muse, mutect2, varscan2
- CUBN | c.5395C>T p.R1799C | Missense Mutation (SNP) | VAF 46/420 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139724058, COSV64726589; called by muse, mutect2, varscan2
- EBF1 | c.1473C>A p.Y491* | Nonsense Mutation (SNP) | VAF 59/619 reads (10%) | catalogued as COSV58190459; called by muse, mutect2
- HDLBP | c.1146G>T p.K382N | Missense Mutation (SNP) | VAF 35/392 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV60501179; called by muse, mutect2
- HNRNPA1 | c.869A>G p.Y290C | Missense Mutation (SNP) | VAF 46/482 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs532469720; called by muse, mutect2
- ICAM1 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 73/754 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375107327; called by muse, mutect2
- NLRP5 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 50/488 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs769534228, COSV101173310; called by muse, mutect2, varscan2
- OR52D1 | c.762C>A p.F254L | Missense Mutation (SNP) | VAF 52/554 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59487023; called by muse, mutect2
- PEG10 | c.518G>A p.R173H (on ENST00000482108 / NM_001040152.2; = p.R207H on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/431 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV71788445; called by muse, mutect2
- PLXNA1 | c.3230G>A p.R1077H | Missense Mutation (SNP) | VAF 51/494 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs772360004, COSV52524629; called by muse, mutect2, varscan2
- RP1L1 | c.6644C>T p.P2215L | Missense Mutation (SNP) | VAF 76/826 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs187850525, COSV66756132; ClinVar: benign; called by muse, mutect2
- SDR42E2 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 52/502 reads (10%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.802); catalogued as rs1027761752; called by muse, mutect2
- SLC30A8 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 34/384 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs777302856, COSV69969419, COSV69969771; called by muse, mutect2
- SLC6A3 | c.1762C>T p.R588* | Nonsense Mutation (SNP) | VAF 44/522 reads (8%) | catalogued as rs1333211743, COSV54368060; called by muse, mutect2
- SLCO5A1 | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 60/548 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV52657021; called by muse, mutect2, varscan2
- STARD13 | c.1285G>T p.G429C (on ENST00000336934 / NM_001243476.3; = p.G311C on NM_052851.3) | Missense Mutation (SNP) | VAF 36/544 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs766966058; called by muse, mutect2
- TBL1X | c.947C>T p.T316M | Missense Mutation (SNP) | VAF 46/562 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as rs892295499, COSV54274289; called by muse, mutect2
- TINAG | c.567A>T p.K189N | Missense Mutation (SNP) | VAF 86/549 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs758756157, COSV52505411; called by muse, mutect2, varscan2
- TNC | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 59/286 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201625385; called by muse, mutect2, varscan2
- TSSK1B | c.1091C>T p.T364M | Missense Mutation (SNP) | VAF 42/430 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.074); catalogued as rs372882864; called by muse, mutect2
- VOPP1 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 43/478 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs761342498, COSV53390629; called by muse, mutect2
- ZFP36 | c.116G>T p.G39V (on ENST00000594442; = p.G33V on NM_003407.5) | Missense Mutation (SNP) | VAF 89/652 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1171613603, COSV50529287; called by muse, mutect2, varscan2
- ZNF304 | c.572G>T p.R191M | Missense Mutation (SNP) | VAF 76/450 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as COSV99988441; called by muse, mutect2, varscan2
- ZNF728 | c.142C>G p.P48A | Missense Mutation (SNP) | VAF 14/289 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV74099170; called by muse, mutect2
- ZNRF3 | c.2581C>T p.P861S (on ENST00000544604 / NM_001206998.2; = p.P761S on NM_032173.3) | Missense Mutation (SNP) | VAF 72/657 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.026); catalogued as rs1362029790; called by muse, mutect2, varscan2
- ADNP | c.587A>T p.Y196F | Missense Mutation (SNP) | VAF 26/383 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- ATP10A | c.4003G>A p.G1335R | Missense Mutation (SNP) | VAF 58/564 reads (10%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDKL5 | c.1637G>T p.G546V | Missense Mutation (SNP) | VAF 62/459 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- DMD | c.9367C>A p.L3123I | Missense Mutation (SNP) | VAF 22/418 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAH6 | c.5396G>A p.G1799D | Missense Mutation (SNP) | VAF 36/364 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.737); called by muse, mutect2
- DSP | c.5279A>G p.N1760S | Missense Mutation (SNP) | VAF 63/456 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- FNBP1 | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 50/332 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSIP2 | c.10544C>A p.S3515Y | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.788); called by muse, mutect2
- GLDC | c.956G>T p.R319I | Missense Mutation (SNP) | VAF 40/644 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GPC6 | c.798C>A p.C266* | Nonsense Mutation (SNP) | VAF 44/612 reads (7%) | called by muse, mutect2
- GPR34 | c.254A>C p.K85T | Missense Mutation (SNP) | VAF 93/560 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GYS1 | c.829G>T p.V277L | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.036); called by muse, mutect2
- HACE1 | c.1343C>A p.T448K | Missense Mutation (SNP) | VAF 38/455 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.136); called by muse, mutect2
- HOXC6 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 41/317 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL13RA2 | c.286G>T p.D96Y | Missense Mutation (SNP) | VAF 28/347 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KL | c.2581T>A p.F861I | Missense Mutation (SNP) | VAF 42/614 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2
- NBPF12 | c.2770T>C p.C924R | Missense Mutation (SNP) | VAF 30/518 reads (6%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.997); called by muse, mutect2
- NOMO3 | c.233T>G p.F78C | Missense Mutation (SNP) | VAF 29/306 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NOS1AP | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 51/528 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NSD2 | c.1073A>G p.Q358R | Missense Mutation (SNP) | VAF 59/435 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLR3B | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 36/410 reads (9%) | SIFT tolerated (0.81); PolyPhen benign (0.03); called by muse, mutect2
- PTGER2 | c.523_546del p.Y175_C182del | In Frame Del (DEL) | VAF 44/492 reads (9%) | called by mutect2, pindel
- SCN9A | c.3080C>A p.A1027E (on ENST00000303354; = p.A1016E on NM_002977.3) | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- SLC47A2 | c.490A>T p.I164F | Missense Mutation (SNP) | VAF 29/336 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2
- STK32C | c.876+1G>A p.X292_splice | Splice Site (SNP) | VAF 41/367 reads (11%) | called by muse, mutect2, varscan2
- SYN1 | c.848A>G p.D283G | Missense Mutation (SNP) | VAF 56/384 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- TAF11L13 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- TRIM13 | c.657C>G p.I219M | Missense Mutation (SNP) | VAF 40/317 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UNC13C | c.554G>C p.R185T | Missense Mutation (SNP) | VAF 42/435 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); called by muse, mutect2
- ZCRB1 | c.350G>A p.S117N | Missense Mutation (SNP) | VAF 23/356 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZFP62 | c.878G>A p.S293N (on ENST00000502412 / NM_001377944.1; = p.S260N on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/588 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.098); called by muse, mutect2
- ZNF592 | c.2669G>T p.G890V | Missense Mutation (SNP) | VAF 43/392 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.107); called by mutect2, varscan2
- ABCA8 | c.1965C>T p.C655= | Silent (SNP) | VAF 24/370 reads (6%) | catalogued as rs781158837, COSV52194068; called by muse, mutect2
- AC099489.1 | c.8862A>G p.S2954= | Silent (SNP) | VAF 44/448 reads (10%) | called by muse, mutect2
- ATP10A | c.2004C>T p.N668= | Silent (SNP) | VAF 69/574 reads (12%) | catalogued as rs890489585, COSV63513674; called by muse, mutect2, varscan2
- CELSR1 | c.990G>A p.T330= | Silent (SNP) | VAF 44/569 reads (8%) | called by muse, mutect2
- CERS4 | c.447C>T p.G149= | Silent (SNP) | VAF 40/496 reads (8%) | catalogued as rs370819639; called by muse, mutect2
- DRAXIN | c.21C>T p.H7= | Silent (SNP) | VAF 46/492 reads (9%) | called by muse, mutect2, varscan2
- FAM178B | c.147G>T p.V49= | Silent (SNP) | VAF 39/337 reads (12%) | called by muse, mutect2, varscan2
- FAM78A | c.177C>T p.S59= | Silent (SNP) | VAF 118/478 reads (25%) | catalogued as rs1313239349; called by muse, mutect2, varscan2
- GABRA1 | c.90A>C p.S30= | Silent (SNP) | VAF 13/280 reads (5%) | called by muse, mutect2
- GOLGA8H | c.1806G>A p.P602= | Silent (SNP) | VAF 58/798 reads (7%) | catalogued as rs749174179; called by muse, mutect2
- GRM3 | c.903C>T p.D301= | Silent (SNP) | VAF 54/638 reads (8%) | catalogued as COSV64475973; called by muse, mutect2
- IRGQ | c.627G>A p.A209= | Silent (SNP) | VAF 121/542 reads (22%) | catalogued as rs377156282; called by muse, mutect2, varscan2
- JPH2 | c.1128C>T p.A376= | Silent (SNP) | VAF 60/524 reads (11%) | catalogued as rs200272307, COSV65902727; called by muse, mutect2, varscan2
- KALRN | c.2337C>A p.I779= | Silent (SNP) | VAF 25/240 reads (10%) | called by muse, mutect2, varscan2
- KLHL25 | c.1116G>A p.A372= | Silent (SNP) | VAF 54/668 reads (8%) | catalogued as rs139047535; called by muse, mutect2
- LRPPRC | c.2395A>C p.R799= | Silent (SNP) | VAF 45/491 reads (9%) | catalogued as rs1394324745, COSV53244485; called by muse, mutect2
- MAD1L1 | c.1911C>T p.T637= | Silent (SNP) | VAF 44/568 reads (8%) | catalogued as rs373029162, COSV56248462, COSV99766030; called by muse, mutect2
- MXRA5 | c.6528G>A p.P2176= | Silent (SNP) | VAF 95/545 reads (17%) | catalogued as rs1188399848, COSV54246756, COSV99478045; called by muse, mutect2, varscan2
- OLIG3 | c.564G>A p.A188= | Silent (SNP) | VAF 44/643 reads (7%) | called by muse, mutect2
- PEG3 | c.231G>A p.P77= | Silent (SNP) | VAF 49/571 reads (9%) | catalogued as rs760648993, COSV55630487, COSV55632817; called by muse, mutect2
- PKHD1 | c.2049G>T p.V683= | Silent (SNP) | VAF 32/568 reads (6%) | called by muse, mutect2
- PPP2R5A | c.159G>C p.L53= | Silent (SNP) | VAF 47/464 reads (10%) | called by muse, mutect2
- RNF180 | c.936T>C p.C312= | Silent (SNP) | VAF 28/452 reads (6%) | called by muse, mutect2
- SLC19A1 | c.645C>T p.D215= | Silent (SNP) | VAF 44/556 reads (8%) | catalogued as rs759174219, COSV60755266; called by muse, mutect2
- SYT6 | c.444G>A p.S148= (on ENST00000610222 / NM_001366225.1; = p.S63= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/497 reads (11%) | catalogued as rs1379520167, COSV65773315, COSV65776115; called by muse, mutect2, varscan2
- TMEM132C | c.2427C>T p.G809= | Silent (SNP) | VAF 43/421 reads (10%) | called by muse, mutect2, varscan2
- ZNF335 | c.2301G>A p.L767= | Silent (SNP) | VAF 49/419 reads (12%) | called by muse, mutect2, varscan2
- ANKMY1 | c.-54A>G | 5'UTR (SNP) | VAF 50/604 reads (8%) | called by muse, mutect2
- FAAP100 | c.*607C>T | 3'UTR (SNP) | VAF 60/526 reads (11%) | called by muse, mutect2, varscan2
- LDB3 | c.896+6753C>T | Intron (SNP) | VAF 28/258 reads (11%) | catalogued as rs121908335, CM050286; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPIA | c.-1C>T | 5'UTR (SNP) | VAF 38/346 reads (11%) | catalogued as rs1452362299; called by muse, varscan2
- TRIOBP | c.5322+5258C>T | Intron (SNP) | VAF 30/263 reads (11%) | called by muse, mutect2, varscan2
